Somatic mutation profile of tumor specimen TCGA-24-1427-01A (aliquot TCGA-24-1427-01A-01W-0549-09) from TCGA case TCGA-24-1427, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.7 years (21,423 days).
Specimen TCGA-24-1427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b31eddd4-a867-432f-b7bf-f2a1cd95265a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1427-10A (Blood Derived Normal), aliquot TCGA-24-1427-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffe1f4ee-7f69-428f-9bfc-c7e40499f545

The open-access MAF lists 73 somatic variants for this specimen: 57 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 47, Silent 16, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57869521; called by muse, mutect2, varscan2
- AGAP3 | c.568G>A p.E190K (on ENST00000622464; = p.E226K on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV58994003; called by muse, mutect2, varscan2
- ALB | c.353A>C p.Q118P | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.609); catalogued as COSV99890378; called by muse, mutect2
- ALK | c.675C>A p.S225R | Missense Mutation (SNP) | VAF 137/594 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV66586205, COSV66589558; called by muse, mutect2, varscan2
- APLP2 | c.1920G>T p.E640D | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.638); catalogued as COSV53843700; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1919T>C p.I640T | Missense Mutation (SNP) | VAF 135/197 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs752360259, COSV63247005; called by muse, mutect2, varscan2
- BMP10 | c.522A>T p.K174N | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV54896716; called by muse, mutect2, varscan2
- CENPN | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV100000991; called by muse, mutect2
- CLASP2 | c.2663G>T p.W888L | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56291803; called by muse, mutect2, varscan2
- CXADR | c.344T>A p.I115N | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.261); catalogued as COSV53030929; called by muse, mutect2, varscan2
- CYP2C19 | c.472A>C p.K158Q | Missense Mutation (SNP) | VAF 162/596 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV64909053; called by muse, varscan2
- FEM1C | c.314A>G p.H105R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs771619711, COSV57232559; called by muse, mutect2, varscan2
- FO393400.1 | c.214G>C p.V72L | Missense Mutation (SNP) | VAF 42/492 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); catalogued as rs754807110, COSV54071068, COSV99640489; called by muse, mutect2
- GPRIN3 | c.1518C>A p.D506E | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60886274; called by muse, mutect2, varscan2
- GRIK2 | c.2310G>C p.M770I | Missense Mutation (SNP) | VAF 63/356 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV59762554; called by muse, mutect2
- HAS2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 460/830 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58266656; called by muse, mutect2, varscan2
- HINFP | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100640795; called by muse, mutect2
- ILK | c.172dup p.A58Gfs*11 | Frame Shift Ins (INS) | VAF 5/33 reads (15%) | catalogued as rs770182262; called by mutect2, pindel
- ITGB6 | c.59A>C p.Q20P | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV99323978; called by muse, mutect2
- KDR | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as COSV55759589; called by muse, mutect2, varscan2
- KIAA0100 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772583261, COSV66495852; called by muse, mutect2, varscan2
- KIRREL3 | c.1832A>G p.D611G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV101375159; called by muse, mutect2
- LTBR | c.734_736del p.S245del | In Frame Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs1565495343; called by mutect2, varscan2
- MAP3K20 | c.1138C>A p.L380M | Missense Mutation (SNP) | VAF 28/650 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV100919323; called by muse, mutect2
- MARK2 | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 251/669 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59288057; called by muse, mutect2, varscan2
- MFSD9 | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV51495362; called by muse, mutect2
- MKRN2 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99402857; called by muse, mutect2
- MUC5B | c.6185C>T p.T2062I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV71594697; called by muse, mutect2, varscan2
- MYLK | c.5111T>C p.M1704T | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs146600235; called by muse, mutect2, varscan2
- NDUFA9 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV56931582; called by muse, mutect2, varscan2
- NES | c.3430C>A p.L1144I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV63962601; called by muse, mutect2
- NRXN1 | c.2764C>A p.Q922K | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.659); catalogued as COSV58485229; called by muse, mutect2, varscan2
- NSUN5 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53091855; called by muse, mutect2
- OR10K1 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 80/590 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56872924, COSV56873725; called by muse, mutect2, varscan2
- OR1A1 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 178/437 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs775579184, COSV58404531; called by muse, mutect2, varscan2
- PARS2 | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 46/150 reads (31%) | catalogued as COSV64883897; called by muse, mutect2, varscan2
- PLB1 | c.3527G>T p.R1176M | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV59833867; called by muse, mutect2, varscan2
- POLQ | c.6835C>T p.P2279S | Missense Mutation (SNP) | VAF 166/458 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.335); catalogued as COSV51759535; called by muse, mutect2, varscan2
- RYR2 | c.5010C>G p.H1670Q | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV100769005, COSV63708384; called by muse, mutect2, varscan2
- SEC14L1 | c.1612-1G>T p.X538_splice | Splice Site (SNP) | VAF 64/100 reads (64%) | catalogued as COSV101170803; called by muse, mutect2, varscan2
- SEC14L1 | c.1612A>T p.I538F | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV101170804; called by muse, mutect2, varscan2
- SETD2 | c.2947G>T p.E983* | Nonsense Mutation (SNP) | VAF 61/291 reads (21%) | catalogued as COSV100339032, COSV57448366; called by muse, mutect2, varscan2
- SIGLEC8 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.218); catalogued as COSV58475467; called by muse, mutect2, varscan2
- SLC26A7 | c.878+2T>G p.X293_splice | Splice Site (SNP) | VAF 43/393 reads (11%) | catalogued as COSV52602946; called by muse, mutect2, varscan2
- SLCO1B1 | c.71G>T p.C24F | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs771380189, COSV57011769; called by muse, mutect2, varscan2
- THEM5 | c.370G>T p.G124* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV64313025, COSV64313078; called by muse, mutect2, varscan2
- TNIK | c.2465C>G p.P822R | Missense Mutation (SNP) | VAF 180/622 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52693207; called by muse, mutect2, varscan2
- TP53 | c.814del p.V272Cfs*73 | Frame Shift Del (DEL) | VAF 67/134 reads (50%) | catalogued as CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; called by mutect2, pindel, varscan2
- TRIOBP | c.3120C>A p.F1040L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV60383304; called by muse, varscan2
- TRMT10A | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs200328690, COSV56745973; called by muse, mutect2, varscan2
- TRMT11 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57674070; called by muse, mutect2, varscan2
- TRPC1 | c.1797C>A p.F599L (on ENST00000476941 / NM_001251845.2; = p.F565L on NM_003304.4) | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV56424360; called by muse, mutect2, varscan2
- TTN | c.69846C>A p.D23282E (on ENST00000591111; = p.D15858E on NM_003319.4) | Missense Mutation (SNP) | VAF 33/153 reads (22%) | PolyPhen benign (0.069); catalogued as COSV60288283; called by muse, mutect2, varscan2
- WHRN | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 78/117 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs777415661, COSV54330396; called by muse, mutect2, varscan2
- CXorf58 | c.980_*12del | Nonstop Mutation (DEL) | VAF 48/197 reads (24%) | called by mutect2, pindel
- IGKV3D-7 | c.255G>C p.R85S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- RAI14 | c.853-6_861del p.X285_splice | Splice Site (DEL) | VAF 23/151 reads (15%) | called by mutect2, pindel, varscan2
- ANPEP | c.1710C>A p.P570= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs141325059, COSV100262426; called by muse, mutect2, varscan2
- ARHGAP31 | c.1431G>T p.P477= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV99956367; called by muse, mutect2
- ARPP21 | c.159A>G p.R53= | Silent (SNP) | VAF 88/352 reads (25%) | catalogued as COSV99490352; called by muse, mutect2, varscan2
- BAZ2A | c.684A>G p.A228= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV51642579; called by muse, mutect2, varscan2
- BIN1 | c.408C>A p.I136= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV52121409; called by muse, mutect2, varscan2
- CCDC71 | c.894G>A p.K298= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV58910681; called by muse, mutect2, varscan2
- FBXO30 | c.267C>T p.C89= | Silent (SNP) | VAF 38/307 reads (12%) | catalogued as rs764982619, COSV52792167; called by muse, mutect2, varscan2
- LRRTM1 | c.1326G>T p.V442= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54445755, COSV99701727; called by muse, mutect2, varscan2
- LSM3 | c.297G>T p.L99= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV60044335; called by muse, mutect2, varscan2
- MYH14 | c.990G>A p.L330= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV99221296; called by muse, mutect2
- MYH15 | c.939C>G p.L313= | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as COSV56317867; called by muse, mutect2, varscan2
- OR52A1 | c.606T>C p.G202= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV61093155; called by muse, mutect2, varscan2
- SATB2 | c.1800G>A p.A600= | Silent (SNP) | VAF 91/170 reads (54%) | catalogued as rs764410137, COSV53484641; called by muse, mutect2, varscan2
- SYT2 | c.981C>A p.T327= | Silent (SNP) | VAF 138/646 reads (21%) | catalogued as COSV66141784, COSV66142881; called by muse, mutect2, varscan2
- ZDHHC19 | c.109C>T p.L37= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV56349816; called by muse, mutect2, varscan2
- ZNF623 | c.990G>T p.R330= | Silent (SNP) | VAF 41/495 reads (8%) | catalogued as COSV101513428; called by muse, mutect2
